Somatic mutation profile of tumor specimen TCGA-CC-A8HS-01A (aliquot TCGA-CC-A8HS-01A-11D-A35Z-10) from TCGA case TCGA-CC-A8HS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 18.1 years (6,617 days).
Specimen TCGA-CC-A8HS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 194dd686-c391-4c25-9c91-da95c051a18f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A8HS-10A (Blood Derived Normal), aliquot TCGA-CC-A8HS-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff256720-8c63-434f-b134-c1af3d96f59e

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 9, Nonsense Mutation 3, Intron 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 35/56 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.057); catalogued as rs371902412; called by muse, mutect2, varscan2
- ABCA13 | c.11916G>C p.Q3972H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.917); catalogued as COSV101446693; called by muse, mutect2, varscan2
- AC011479.1 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 153/213 reads (72%) | SIFT deleterious, low confidence (0); catalogued as COSV100007756; called by muse, mutect2, varscan2
- ANKIB1 | c.2225G>C p.R742T | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99728055; called by muse, mutect2
- ARHGEF3 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99574705; called by muse, mutect2, varscan2
- BOC | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); catalogued as rs771932279, COSV99847793; called by muse, mutect2, varscan2
- CGN | c.2768A>G p.Q923R | Missense Mutation (SNP) | VAF 57/511 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV99641702; called by muse, mutect2, varscan2
- DZIP1 | c.2170A>G p.T724A (on ENST00000347108; = p.T705A on NM_014934.5) | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV100713964; called by muse, mutect2, varscan2
- ELMO3 | c.1133A>G p.E378G (on ENST00000652269; = p.E325G on NM_024712.5) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as COSV62607900; called by mutect2, varscan2
- ENGASE | c.1799G>T p.R600L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.427); catalogued as COSV100285612; called by muse, mutect2, varscan2
- FLNA | c.5146C>A p.Q1716K (on ENST00000369850 / NM_001110556.2; = p.Q1708K on NM_001456.3) | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT tolerated (0.37); PolyPhen benign (0.309); catalogued as COSV61048769; called by muse, mutect2, varscan2
- FLT3 | c.2567C>A p.A856D | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99606928, COSV99607712; called by muse, mutect2, varscan2
- GALNT18 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99923453; called by muse, mutect2, varscan2
- GCLM | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV100933961; called by muse, mutect2, varscan2
- GPR149 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV101078006; called by muse, mutect2, varscan2
- HECTD4 | c.4188G>C p.M1396I | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100295740; called by muse, mutect2
- KIF26B | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831454; called by muse, mutect2, varscan2
- KLHDC3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99763490; called by muse, mutect2, varscan2
- MRC1 | c.271T>G p.C91G | Missense Mutation (SNP) | VAF 226/621 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100509455; called by muse, mutect2, varscan2
- MUC16 | c.13435C>A p.P4479T | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV101197346; called by muse, mutect2, varscan2
- MYO10 | c.3854A>T p.D1285V | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV99944422; called by muse, mutect2, varscan2
- NLRP10 | c.1882A>G p.K628E | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100149404; called by muse, mutect2
- NRXN1 | c.3980C>G p.T1327S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100639454; called by muse, mutect2, varscan2
- OR2T4 | c.925T>C p.F309L | Missense Mutation (SNP) | VAF 219/749 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV100822381; called by muse, mutect2, varscan2
- OR6F1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100128845, COSV100128870; called by muse, mutect2, varscan2
- PDE3A | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV100761480; called by muse, mutect2, varscan2
- PTPN21 | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.525); catalogued as rs1243589250, COSV100161330; called by muse, mutect2, varscan2
- PTPRC | c.1862G>A p.R621K | Missense Mutation (SNP) | VAF 229/402 reads (57%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV100721973; called by muse, mutect2, varscan2
- ROS1 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 50/97 reads (52%) | catalogued as COSV100876024; called by muse, mutect2, varscan2
- SCNN1B | c.353T>A p.L118Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV100225271, COSV100225808; called by muse, mutect2, varscan2
- SPEG | c.7814G>A p.C2605Y | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100402969; called by muse, mutect2, varscan2
- STOML3 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV101105108; called by muse, mutect2, varscan2
- SUSD5 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs377664152; called by muse, mutect2, varscan2
- TENM2 | c.5314A>T p.N1772Y (on ENST00000518659 / NM_001122679.2; = p.N1533Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101317480; called by muse, mutect2, varscan2
- TMA16 | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100667229; called by muse, mutect2, varscan2
- TMC4 | c.1567A>G p.T523A (on ENST00000617472 / NM_001145303.3; = p.T517A on NM_144686.4) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.073); catalogued as COSV99713669; called by muse, mutect2, varscan2
- TUT1 | c.2314C>T p.H772Y | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1291986477, COSV99544819; called by muse, mutect2, varscan2
- WASHC2C | c.1667T>G p.L556* | Nonsense Mutation (SNP) | VAF 146/380 reads (38%) | catalogued as COSV100313735; called by muse, mutect2, varscan2
- ZFYVE26 | c.2571C>A p.N857K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as COSV100719941; called by muse, mutect2
- ZNF28 | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 72/101 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100354204; called by muse, mutect2, varscan2
- ZNF676 | c.1463A>C p.K488T (on ENST00000650058; = p.K456T on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV101236067; called by muse, mutect2, varscan2
- HPGD | c.588del p.E197Kfs*8 | Frame Shift Del (DEL) | VAF 33/63 reads (52%) | called by mutect2, pindel, varscan2
- MRC1 | c.3760A>T p.R1254* | Nonsense Mutation (SNP) | VAF 165/425 reads (39%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.2433G>A p.K811= | Silent (SNP) | VAF 8/55 reads (15%) | called by mutect2, varscan2
- ATP4A | c.1068C>T p.S356= | Silent (SNP) | VAF 42/58 reads (72%) | catalogued as rs1269407415, COSV52870097; called by muse, mutect2, varscan2
- HTR1F | c.873A>G p.A291= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100137874; called by muse, mutect2, varscan2
- KRT6B | c.636G>A p.P212= | Silent (SNP) | VAF 34/264 reads (13%) | catalogued as rs143150216; called by muse, mutect2, varscan2
- NLRP5 | c.1932C>T p.D644= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs776601668, COSV101173547, COSV66762842; called by muse, mutect2, varscan2
- RPL4 | c.315C>G p.T105= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV100328324; called by muse, mutect2, varscan2
- STOML2 | c.918C>T p.T306= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV99956337; called by muse, mutect2
- TEP1 | c.4305G>A p.L1435= | Silent (SNP) | VAF 57/107 reads (53%) | catalogued as COSV99401353; called by muse, mutect2, varscan2
- TEX44 | c.1167G>A p.Q389= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV100009541; called by muse, mutect2, varscan2
- IFT122 | c.273-267G>T | Intron (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99958538; called by muse, mutect2, varscan2
- MIR143 | n.69A>G | RNA (SNP) | VAF 3/38 reads (8%) | catalogued as rs1275333653; called by muse, mutect2
